Somatic mutation profile of tumor specimen 0DI3JY from CCDI case PBBUPA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myxoid liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 16.5 years (6,033 days).
Specimen 0DI3JY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df8ddb29-a9cf-4fe1-9e34-3ad40249b5d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI1L4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d83ac10-8c64-4879-84d8-5b1ffe5c54b4

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPFFR1 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 142/344 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.183); catalogued as rs1405152190; called by muse, varscan2
- HOOK2 | c.1104+1G>A p.X368_splice | Splice Site (SNP) | VAF 46/148 reads (31%) | called by muse, varscan2
- METRN | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, varscan2
- OR52B4 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 194/707 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, varscan2
- MYLK | c.3900G>A p.A1300= | Silent (SNP) | VAF 184/536 reads (34%) | catalogued as rs563116446, COSV60613110; ClinVar: uncertain significance; called by muse, varscan2
- OGDHL | c.1197C>T p.A399= | Silent (SNP) | VAF 38/154 reads (25%) | catalogued as rs139847941; called by muse, varscan2
- ZNF75A | c.-316+2978G>A | Intron (SNP) | VAF 144/514 reads (28%) | called by muse, varscan2
